Somatic mutation profile of tumor specimen TCGA-50-6591-01A (aliquot TCGA-50-6591-01A-11D-1753-08) from TCGA case TCGA-50-6591, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.2 years (23,067 days).
Specimen TCGA-50-6591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade64044-3918-4bdc-a392-3e0663bc4424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6591-11A (Solid Tissue Normal), aliquot TCGA-50-6591-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd44bad1-37f5-4191-8915-7da80c02f565

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, In Frame Del 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2260_2277del p.K754_I759del | In Frame Del (DEL) | VAF 149/223 reads (67%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- EGFR | c.2497T>G p.L833V | Missense Mutation (SNP) | VAF 335/363 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs397517126, COSV51773059, COSV51776947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAS1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1555875129, COSV65090342; called by muse, mutect2, varscan2
- CAGE1 | c.1844C>A p.S615Y (on ENST00000512086; = p.S479Y on NM_205864.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV99699955; called by muse, mutect2, varscan2
- CCDC106 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.132); catalogued as rs767137482; called by muse, mutect2, varscan2
- DDX4 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737507; called by muse, mutect2, varscan2
- FANCM | c.2161-1G>C p.X721_splice | Splice Site (SNP) | VAF 8/112 reads (7%) | catalogued as COSV57507492, COSV99950213; called by muse, mutect2
- FRY | c.8783+2T>G p.X2928_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100969558; called by muse, mutect2, varscan2
- GNL3L | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1431817317; called by muse, mutect2, varscan2
- H3-3B | c.379T>G p.L127V | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99638091; called by muse, mutect2
- MYCBP2 | c.11294G>A p.R3765Q (on ENST00000357337; = p.R3803Q on NM_015057.5) | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1265551059; called by muse, mutect2
- OR1L1 | c.654C>A p.F218L (on ENST00000373686; = p.F168L on NM_001005236.3) | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58936943; called by mutect2, varscan2
- OR2T1 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778008045, COSV63541701; called by muse, mutect2, varscan2
- PTGS1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99792980; called by muse, mutect2, varscan2
- RESF1 | c.4916C>T p.P1639L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981497079; called by muse, mutect2, varscan2
- SFXN1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201545749; called by muse, mutect2
- TPI1 | c.245C>T p.P82L (on ENST00000229270; = p.P45L on NM_000365.6) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1012340893; called by muse, varscan2
- TTN | c.64495C>T p.P21499S (on ENST00000591111; = p.P14075S on NM_003319.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | PolyPhen probably damaging (0.998); catalogued as COSV60253208; called by muse, mutect2, varscan2
- ASAP3 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CBX4 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.074); called by mutect2, varscan2
- CD1A | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- COL27A1 | c.4630G>A p.G1544R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLK1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DSG4 | c.2948C>T p.T983I | Missense Mutation (SNP) | VAF 94/99 reads (95%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FOXO4 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H2BC11 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KLB | c.1040_1045del p.K347_F349delinsI | In Frame Del (DEL) | VAF 40/87 reads (46%) | called by mutect2, pindel, varscan2
- LMO2 | c.395G>C p.G132A (on ENST00000395833 / NM_001142315.2; = p.G201A on NM_005574.4) | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRPS15 | c.417T>A p.Y139* | Nonsense Mutation (SNP) | VAF 84/199 reads (42%) | called by muse, mutect2, varscan2
- NEDD4 | c.2662T>G p.S888A (on ENST00000508342 / NM_001284338.1; = p.S469A on NM_006154.4) | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PROP1 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPN9 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTPRD | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RESF1 | c.4915C>G p.P1639A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1A | c.160T>G p.S54A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SELP | c.2188T>C p.C730R | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L2 | c.4267dup p.E1423Gfs*28 | Frame Shift Ins (INS) | VAF 67/98 reads (68%) | called by mutect2, pindel, varscan2
- SLCO4A1 | c.1565A>G p.D522G | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SRCAP | c.5284C>T p.P1762S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53 | c.161del p.F54Sfs*69 | Frame Shift Del (DEL) | VAF 148/214 reads (69%) | called by mutect2, pindel, varscan2
- UCHL5 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 124/161 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF568 | c.1665G>C p.E555D | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ADGRV1 | c.15909C>T p.F5303= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs754492973, COSV67994856; called by muse, mutect2, varscan2
- BTD | c.1371G>A p.E457= | Silent (SNP) | VAF 47/51 reads (92%) | catalogued as rs1480435742; called by muse, mutect2, varscan2
- CSMD2 | c.7215G>A p.E2405= | Silent (SNP) | VAF 125/207 reads (60%) | catalogued as COSV99588651; called by muse, mutect2, varscan2
- DOCK8 | c.1596C>G p.P532= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs1469007115; called by muse, mutect2, varscan2
- H3C8 | c.291C>T p.C97= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs1337348824, COSV100010119; called by muse, mutect2, varscan2
- IQCA1 | c.1599G>T p.V533= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- PAK6 | c.225G>A p.A75= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs754566912, COSV53045711; called by muse, mutect2, varscan2
- PASD1 | c.2091T>A p.S697= | Silent (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- PLCH1 | c.3813G>A p.T1271= (on ENST00000340059 / NM_001130960.2; = p.T1263= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as rs766465810, COSV58190024; called by muse, mutect2, varscan2
- PTPN9 | c.892A>C p.R298= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS2 | c.543G>T p.G181= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV59826502; called by muse, mutect2, varscan2
- PVRIG | chr7:100223998 A>C | 3'Flank (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99443965; called by muse, mutect2, varscan2
